Somatic mutation profile of tumor specimen 0DQ2NH from CCDI case PBCENU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.0 years (5,497 days).
Specimen 0DQ2NH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a81cc291-13a9-401b-b434-35dc6d0bf3a2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DQ2P2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1982ab04-ee58-4329-9db4-8f41bd3b4958

The open-access MAF lists 19 somatic variants for this specimen: 7 protein-altering or splice-affecting, 5 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Intron 6, Silent 5, Nonsense Mutation 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 194/385 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ELOVL7 | c.317G>A p.R106Q | Missense Mutation (SNP) | VAF 237/507 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs779998858; called by muse, mutect2, varscan2
- LIN28B | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 193/376 reads (51%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs76912525, COSV61498203; called by muse, mutect2, varscan2
- SEC23A | c.2147G>A p.R716H | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1351692320, COSV56979427; called by muse, mutect2, varscan2
- DHX38 | c.523A>G p.R175G | Missense Mutation (SNP) | VAF 107/208 reads (51%) | SIFT tolerated (0.24); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FREM3 | c.5926G>C p.E1976Q | Missense Mutation (SNP) | VAF 158/299 reads (53%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- SPON2 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 101/217 reads (47%) | called by muse, mutect2, varscan2
- ANKRD33 | c.582C>T p.F194= (on ENST00000340970 / NM_001304459.2; = p.F319= on NM_182608.4) | Silent (SNP) | VAF 156/326 reads (48%) | catalogued as rs768409817, COSV100001469; called by muse, mutect2, varscan2
- CNTNAP5 | c.1833C>T p.S611= | Silent (SNP) | VAF 186/349 reads (53%) | catalogued as rs747709967, COSV101442956; called by muse, mutect2, varscan2
- PLCH1 | c.987G>C p.V329= (on ENST00000340059 / NM_001130960.2; = p.V341= on NM_014996.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 32/495 reads (6%) | catalogued as COSV58211044; called by muse, mutect2
- POLR2A | c.5901C>T p.D1967= | Silent (SNP) | VAF 164/376 reads (44%) | catalogued as rs755251075; called by muse, mutect2, varscan2
- WSCD1 | c.1233C>T p.H411= | Silent (SNP) | VAF 194/413 reads (47%) | catalogued as rs779243628, COSV100496882; called by muse, mutect2, varscan2
- ANKS1A | c.3402-96del | Intron (DEL) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- BACE2 | c.312+11064A>C | Intron (SNP) | VAF 71/142 reads (50%) | called by muse, mutect2, varscan2
- EYS | c.1767-6642G>A | Intron (SNP) | VAF 171/586 reads (29%) | catalogued as rs770019576; called by muse, mutect2, varscan2
- KALRN | c.1765-71G>A | Intron (SNP) | VAF 90/176 reads (51%) | catalogued as rs971355899; called by muse, mutect2, varscan2
- KRT18 | c.948+45C>G | Intron (SNP) | VAF 39/81 reads (48%) | called by muse, mutect2, varscan2
- LINC01517 | n.495G>A | RNA (SNP) | VAF 69/451 reads (15%) | catalogued as rs758631504; called by muse, mutect2, varscan2
- SLC25A30 | c.835-87A>C | Intron (SNP) | VAF 32/63 reads (51%) | called by muse, mutect2, varscan2
